Gene-level copy-number profile of tumor specimen TCGA-Z6-A8JE-01A from TCGA case TCGA-Z6-A8JE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 57.1 years (20,855 days).
Specimen TCGA-Z6-A8JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.bd136b32-2543-4797-b911-12a7f3706dd1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Z6-A8JE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c675a2ef-3740-4cb3-9ad2-0b75bed554b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 137; copy number 1: 5,575; copy number 2: 27,242; copy number 3: 22,270; copy number 4: 2,784; copy number 5: 836; copy number 6: 675; copy number 7: 181; copy number 11: 13; copy number 16: 14; copy number 21: 52; copy number 25: 12; copy number 26: 20; copy number 27: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Z6-A8JE-01A-11D-A37B-01): tumor purity 0.66, ploidy 2.45, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 137 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,084,155–90,261,708, 123 genes (broad region; genes not listed).
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,809 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,953,590–118,264,489, 3 genes, copy number 6 (within-gene range 2–6): SPAG17, AL391557.1, RNA5SP56.
- chr2:102,249,857–103,403,712, 18 genes, copy number 5: FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9, TMEM182, LINC01796, LINC01935, AC108051.1, AC073987.1, AC010881.1, AC011593.1.
- chr2:190,504,338–192,044,525, 27 genes, copy number 5 (within-gene range 2–5): NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1.
- chr5:58,198–45,895,970, 710 genes, copy number 5–7 (broad region; genes not listed).
- chr7:16,087,525–17,346,152, 22 genes, copy number 5 (within-gene range 3–5): CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3.
- chr11:67,735,600–69,926,813, 68 genes, copy number 6 (broad region; genes not listed).
- chr12:24,566,964–26,299,290, 40 genes, copy number 16–27 (within-gene range 2–27): LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5.
- chr12:31,363,481–31,615,666, 12 genes, copy number 25 (within-gene range 2–25): LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50.
- chr14:18,333,726–37,596,059, 667 genes, copy number 6–21 (broad region; genes not listed).
- chr14:37,720,425–37,720,561, 1 gene, copy number 21: AL136296.1.
- chr19:12,284,337–12,681,880, 34 genes, copy number 5 (within-gene range 3–5): AC012618.2, ZNF563, ZNF442, RPS29P23, AC008758.4, AC008758.3, ZNF799, AC008758.5, ZNF443, AC008758.6, AC008758.2, ZNF709, AC008758.1, MTND2P40, MTCO1P27, MTCO2P27, MTATP6P27, PPIAP20, ZNF564, AC010422.6, AC010422.4, AC010422.1, PGK1P2, ZNF490, ZNF791, RPL10P16, AC010422.3, MAN2B1, AC010422.5, WDR83, AC010422.8, WDR83OS, AC010422.7, DHPS.
- chr20:53,936,777–54,070,594, 1 gene, copy number 5 (within-gene range 4–5): BCAS1.
- chr20:54,068,408–57,601,200, 58 genes, copy number 5 (within-gene range 4–5): MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1.
- chr20:60,755,001–64,313,132, 148 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,675. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
